Surgical pathology report (de-identified scan), TCGA case TCGA-3M-AB47, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Kansas Medical Center, specimen TCGA-3M-AB47-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

NAME:	SURG PATH #:
MR #:	SPECIMEN CLASS:
BILLING #:	ALT ID #:
LOCATION:	DATE OF PROCEDURE:
AGE:	DATE RECEIVED:
DOB:	TIME RECEIVED:
PHYSICIAN:	DATE OF REPORT:
COPY TO:	DATE OF PRINTING:

Material Received:

A: stomach and d1, d2 lymph nodes stitch proximal through esophagus
B: small bowel segment

History:

-year-old male.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Stomach NOS C16.9
MD 5/30/14

Final Diagnosis:

A. Stomach, esophagus and lymph nodes, gastrectomy:

Stomach: Invasive poorly differentiated adenocarcinoma, extensively involving the entire stomach wall with extension into surrounding fibroconnective tissue. See checklist.

Esophagus: Squamous mucosa, no evidence of malignancy.

Lymph nodes (15): Positive for metastatic adenocarcinoma in eleven of fifteen lymph nodes (11/15)

B. Small bowel mucosa, "small bowel segment", duodenectomy:

No diagnostic abnormalities.

Comment:

Gastric cancer checklist:

Specimen Type: Gastrectomy

Tumor Configuration: Diffuse

Tumor Size: 17.0 x 8.0 x 2.0 cm

Surgical Margins:

Proximal Margin: Negative for tumor

Distal Margin: Negative for tumor

Circumferential (Radial) Margin: Extensively involved by invasive adenocarcinoma

Histologic Type: Invasive adenocarcinoma

Histologic Grade: Poorly differentiated

Lymphatic (Small Vessel) Invasion: Present

Venous (Large Vessel) Invasion: Present

Perineural Invasion: Present

Lymph Nodes:

Number Examined: 15

Number Involved: 11

Prognostic Markers: Ordered See for addendum Image Analysis report

Pathologic Staging: pT3 N2 Mx

Primary Tumor (pT)

MR #:

Page 1 of 3

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

pT3: Tumor penetrates serosa (visceral peritoneum) without invasion of adjacent structures
Regional Lymph Nodes (pN)

pN2: Metastasis in 7 to 15 perigastric lymph nodes
Specify: Number examined: 15
Number involved: 11

Distant Metastasis (pM)
pMX: Cannot be assessed

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Electronically Signed Out By

Interpreted by:

Gross Description:

A. Received fresh labeled with the patient's name and "stomach and D1, D2 lymph nodes" is a total gastrectomy specimen measuring 24.0 x 11.5 x 5.0 cm. There is an attached mesentery measuring 30.0 x 18.5 x 3.5 cm. The gastric serosal surface is yellow-tan, nodular and firm. The specimen was previously opened in the operating room to reveal a diffuse infiltrating nodular tumor measuring 17 x 8 x 2 cm. There is a small section of normal gastric mucosa. Grossly the mass is located 5 cm from the proximal margin and 9 cm from the distal margin. The tumor extends through the serosa and into the surrounding perigastric fat in multiple areas. The rugal folds are flattened in the area of the tumor. There are multiple grossly obvious lymph nodes, the largest of which measuring 3.0 x 2.0 x 2.5 cm which is located at the distal end of the specimen in the perigastric fat. The specimen is submitted as follows:

A1FS: Lymph node near proximal margin

A2FS: Distal margin

A3FS: Proximal margin

Cassette A4 through A9: Tumor

Cassette A10: Multiple possible lymph nodes

Cassette A11: Multiple possible lymph nodes

Cassette A12: A serial section of the largest lymph node

Cassette A13-A22: Multiple possible lymph nodes

B. Received in formalin labeled with the patient's name and "small bowel segment" is a 4.5 cm in length x 3.9 cm in diameter portion of small intestine. At one end there are four black sutures and the opposite end has a linear row of staples. The sutures end is shaved and bisected and entirely submitted in B1 and B2. The linear row of staples is removed and the tissue deep to that is bisected and entirely submitted in B3-B4. The specimen is opened longitudinally to reveal grossly undulating mucosa with no discrete gross abnormalities identified. Representative sections from the central intestine are submitted in B5.

Intraoperative Consultation:

A1FS, proximal lymph node, "stomach and D1, D2 lymph nodes":
Negative for malignancy.

A2FS, "distal gastric margin":
Negative for malignancy.

A3FS, "gastric biopsy":
Negative for malignancy.

Date of Printing:

MR #:

Page 2 of 3

SURGICAL PATHOLOGY REPORT

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

If immunohistochemical stains and/or in situ hybridization are cited in this report, the performance characteristics were determined by the
in compliance with CLIA'88
regulations. Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the FDA. Known
positive and negative control tissues demonstrate appropriate staining. This testing was developed by the
It has not been cleared or approved by the FDA. The FDA has determined that such clearance or approval
is not necessary.

Date of Printing: ...

MR #:

SURGICAL PATHOLOGY R

Noted:		

Source: NCI Genomic Data Commons file c4ab07fe-3452-456d-a447-b0f673623a62 (TCGA-3M-AB47.55F4DC25-DD4E-44E1-AA0B-7F472060B095.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).